Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5766, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5766-01A (Primary Tumor).

Diagnosis

1. Predominantly poorly differentiated adenocarcinoma of the prostate in the peripheral zone on both sides with left rectolateral predominance. Maximum tumor spread 2.2 cm. Marked perineural tumor invasion. Left rectolateral extraprostatic tumor growth with infiltration of the periprostatic fatty tissue. No identifiable invasion of the vessels. Tumor-free seminal vesicles.
2. Tumor-free portions of seminal vesicle.
3. Two tumor-free lymph nodes.
4. Lymph node micrometastasis of the prostate carcinoma diagnosed under 1. in one of two lymph nodes. Maximum tumor spread 1.9 mm

Remark

In summary, the tumor is classified as follows: pT3a, pN1mi (1/4), L0, V0; Gleason 4+3 = 7 (approx. 80% Gleason 4).

In the region of the tissue defects, carcinoma cells extend to the artefactual preparation margins (yellow labeling). The other preparation margins are tumor-free.

Source: NCI Genomic Data Commons file 01fbd456-891c-48c3-b723-628390abed8f (TCGA-CH-5766.F6F3FDFF-8296-449A-9A1C-D23803CF078A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).